Somatic mutation profile of tumor specimen HCM-CSHL-0808-C55-01A (aliquot HCM-CSHL-0808-C55-01A-11D-A881-36) from HCMI case HCM-CSHL-0808-C55, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC2; FIGO stage: Stage IIIC2.
Specimen HCM-CSHL-0808-C55-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 614b5699-42b1-4d4f-be2b-18c94f7113c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0808-C55-11A (Solid Tissue Normal), aliquot HCM-CSHL-0808-C55-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2681ba2-b16e-4945-958a-5a2587065077

The open-access MAF lists 74 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Splice Region 1, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 57/408 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 45/262 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACA | c.6524G>A p.R2175H | Missense Mutation (SNP) | VAF 49/401 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.917); catalogued as rs145087711; called by muse, mutect2, varscan2
- ADGRG4 | c.6289G>T p.D2097Y | Missense Mutation (SNP) | VAF 25/552 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV54957324; called by muse, mutect2
- ADNP | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 15/366 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62426100; called by muse, mutect2
- AMMECR1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53320478; called by muse, mutect2
- CDH7 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs761625164; called by muse, mutect2
- CUL2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66078682; called by muse, mutect2
- EHBP1L1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279762999; called by muse, mutect2
- HUWE1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53354372; called by muse, mutect2
- IL1RAPL2 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.929); catalogued as COSV100781913, COSV61160693, COSV61187040; called by muse, mutect2
- KIF11 | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs761471421, COSV53268671; called by muse, mutect2, varscan2
- KLHL34 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 24/590 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.207); catalogued as COSV65278709; called by muse, mutect2
- NAP1L3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 27/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59075361; called by muse, mutect2
- PGRMC1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 24/632 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1179307251; called by muse, mutect2
- PIK3CA | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 101/289 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV55908000; called by muse, mutect2, varscan2
- PLK5 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs186235308; called by muse, mutect2, varscan2
- PP2D1 | c.213C>A p.H71Q | Missense Mutation (SNP) | VAF 100/397 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60748589; called by muse, mutect2, varscan2
- PROKR1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV58137109; called by mutect2, varscan2
- PROX1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 21/431 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54775943; called by muse, mutect2
- RLIM | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 43/533 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100223354; called by muse, mutect2
- ROS1 | c.5872G>A p.E1958K | Missense Mutation (SNP) | VAF 13/444 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs986549979; called by muse, mutect2
- SBNO2 | c.730A>C p.S244R | Missense Mutation (SNP) | VAF 90/662 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100684226; called by mutect2, varscan2
- SPRY3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 42/740 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV57141687; called by muse, mutect2
- TSHZ1 | c.2395G>A p.D799N (on ENST00000580243 / NM_001308210.2; = p.D754N on NM_005786.6) | Missense Mutation (SNP) | VAF 27/486 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1020952592, COSV100433806; called by muse, mutect2
- ZNF773 | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV56589303; called by muse, mutect2
- AGTR1 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMBRA1 | c.2303C>T p.S768L (on ENST00000458649 / NM_001367468.1; = p.S678L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2
- AP3B1 | c.2488C>G p.P830A | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BIRC6 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- C1QTNF2 | c.658A>G p.N220D (on ENST00000393975; = p.N175D on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- CPEB3 | c.399dup p.M134Hfs*188 | Frame Shift Ins (INS) | VAF 47/524 reads (9%) | called by mutect2, pindel
- DEUP1 | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 9/272 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- FAM13A | c.1536G>A p.R512= | Splice Region (SNP) | VAF 16/261 reads (6%) | called by muse, mutect2
- FCAR | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 13/389 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); called by muse, mutect2
- FXR1 | c.1395C>G p.I465M | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- GPATCH1 | c.1001-1G>A p.X334_splice | Splice Site (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2, varscan2
- GRPR | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- HLA-DMA | c.711del p.F237Lfs*58 | Frame Shift Del (DEL) | VAF 85/609 reads (14%) | called by mutect2, pindel, varscan2
- KIFBP | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2
- KRT81 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 16/558 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LTBP3 | c.3868C>T p.R1290C (on ENST00000301873 / NM_001130144.3; = p.R1243C on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/584 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAN2B2 | c.2725G>C p.D909H | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.376); called by muse, mutect2
- NOL4 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 6/176 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NUP188 | c.3599A>C p.E1200A | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PCDH17 | c.2416C>T p.L806F | Missense Mutation (SNP) | VAF 14/500 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); called by muse, mutect2
- PPM1H | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRSS12 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- PTPN23 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 95/510 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- SDCCAG8 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 9/333 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- SRBD1 | c.2582C>T p.S861L | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- TCF20 | c.3052A>G p.M1018V | Missense Mutation (SNP) | VAF 20/654 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- TMEM8B | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.972); called by muse, mutect2
- TRGV11 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- UHRF2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); called by muse, mutect2
- AL772284.1 | c.99C>T p.G33= | Silent (SNP) | VAF 49/428 reads (11%) | catalogued as rs1357803202; called by muse, mutect2, varscan2
- BCAR3 | c.331C>T p.L111= | Silent (SNP) | VAF 12/251 reads (5%) | called by muse, mutect2
- BRINP3 | c.301C>T p.L101= | Silent (SNP) | VAF 22/484 reads (5%) | called by muse, mutect2
- CDH18 | c.1317C>T p.T439= | Silent (SNP) | VAF 32/405 reads (8%) | catalogued as COSV56970694; called by muse, mutect2
- DAP3 | c.90A>G p.Q30= | Silent (SNP) | VAF 40/441 reads (9%) | called by muse, mutect2
- FLII | c.12C>G p.T4= | Silent (SNP) | VAF 58/409 reads (14%) | called by muse, mutect2, varscan2
- GPT | c.342G>T p.A114= | Silent (SNP) | VAF 18/340 reads (5%) | catalogued as COSV52952235, COSV52952313, COSV99477330; called by muse, mutect2
- IKZF1 | c.1410C>T p.L470= | Silent (SNP) | VAF 18/524 reads (3%) | called by muse, mutect2
- KRT80 | c.138C>T p.L46= | Silent (SNP) | VAF 25/717 reads (3%) | catalogued as COSV57549278; called by muse, mutect2
- MARK2 | c.720C>G p.L240= | Silent (SNP) | VAF 21/422 reads (5%) | catalogued as rs1193322903; called by muse, mutect2
- MIA2 | c.2412C>T p.T804= | Silent (SNP) | VAF 19/194 reads (10%) | called by muse, mutect2, varscan2
- PRDM2 | c.2667G>A p.Q889= | Silent (SNP) | VAF 11/297 reads (4%) | called by muse, mutect2
- SMC4 | c.1215A>G p.K405= | Silent (SNP) | VAF 51/234 reads (22%) | called by muse, mutect2, varscan2
- TRIM26 | c.1536C>T p.Y512= | Silent (SNP) | VAF 58/673 reads (9%) | catalogued as rs1366502596; called by muse, mutect2
- ZNF100 | c.819C>T p.S273= | Silent (SNP) | VAF 43/367 reads (12%) | catalogued as rs766540094; called by muse, mutect2, varscan2
- ZNF208 | c.1734G>A p.E578= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV101237196; called by muse, mutect2
- ZNF469 | c.3723G>A p.P1241= (on ENST00000437464; = p.P1269= on NM_001367624.2) | Silent (SNP) | VAF 69/568 reads (12%) | catalogued as rs1271108512, COSV71258167; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+27092T>G | Intron (SNP) | VAF 32/305 reads (10%) | called by muse, mutect2, varscan2
- SH3D19 | c.-502G>C | 5'UTR (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
